Somatic mutation profile of tumor specimen 0DUHHV from CCDI case PBCKFB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.1 years (5,881 days).
Specimen 0DUHHV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e7e20f1-cf5d-4bd5-8ba5-e1f4ec426352.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHG6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac36074e-14fd-44f9-b9f0-7228018cfcfa

The open-access MAF lists 45 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Intron 4, 3'UTR 3, 5'UTR 2, Nonsense Mutation 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPS2 | c.716+1G>C p.X239_splice | Splice Site (SNP) | VAF 50/618 reads (8%) | catalogued as COSV60824246; called by muse, mutect2
- CR2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 138/780 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs749471642, COSV100889671; called by muse, mutect2, varscan2
- DCDC1 | c.1618G>C p.G540R | Missense Mutation (SNP) | VAF 235/1417 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs777970181; called by muse, mutect2, varscan2
- FCRL1 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 117/622 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs756244171, COSV63827376; called by muse, mutect2, varscan2
- GPATCH8 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs765357053; called by muse, mutect2, varscan2
- RBFOX1 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 129/846 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV60990372; called by muse, mutect2, varscan2
- WDR36 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 108/1288 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); catalogued as rs771988908; called by muse, mutect2
- ZMYM3 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs748893445, COSV58736234; called by muse, mutect2, varscan2
- AKAP9 | c.5086G>T p.E1696* | Nonsense Mutation (SNP) | VAF 219/1343 reads (16%) | called by muse, mutect2, varscan2
- APLP1 | c.1940T>A p.L647Q (on ENST00000221891 / NM_001024807.3; = p.L646Q on NM_005166.4) | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CUBN | c.10607A>G p.Y3536C | Missense Mutation (SNP) | VAF 128/803 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CYP2D6 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 144/695 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CYP4A22 | c.1215G>T p.L405F | Missense Mutation (SNP) | VAF 181/443 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DHX35 | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 382/1800 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- EFCAB5 | c.1792T>C p.S598P | Missense Mutation (SNP) | VAF 169/1037 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGBP | c.11504G>T p.C3835F | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLRC2 | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 156/958 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KYNU | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 148/948 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRGPRX2 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 133/454 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR51A7 | c.424G>C p.A142P | Missense Mutation (SNP) | VAF 148/994 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- PCDH15 | c.4815G>T p.E1605D | Missense Mutation (SNP) | VAF 57/393 reads (15%) | SIFT tolerated, low confidence (0.1); called by muse, mutect2, varscan2
- PTCH1 | c.2928C>A p.F976L | Missense Mutation (SNP) | VAF 493/911 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A3 | c.279C>A p.H93Q | Missense Mutation (SNP) | VAF 107/810 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF13 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 121/674 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TAS2R16 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 134/954 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TPGS2 | c.889T>G p.F297V | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS37A | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 193/1242 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GPT | c.21C>T p.D7= | Silent (SNP) | VAF 72/510 reads (14%) | called by muse, mutect2, varscan2
- KIF1C | c.996C>T p.Y332= | Silent (SNP) | VAF 63/376 reads (17%) | catalogued as rs143283587; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- NPRL3 | c.225C>G p.T75= | Silent (SNP) | VAF 179/534 reads (34%) | catalogued as rs372639365; ClinVar: likely benign; called by muse, mutect2, varscan2
- ONECUT3 | c.201C>T p.G67= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs995479093; called by muse, varscan2
- PCDHGA12 | c.846G>C p.R282= | Silent (SNP) | VAF 64/530 reads (12%) | called by muse, mutect2, varscan2
- PPIL2 | c.891C>T p.C297= | Silent (SNP) | VAF 48/449 reads (11%) | catalogued as rs763736700; called by muse, mutect2, varscan2
- SREBF2 | c.2199C>A p.G733= | Silent (SNP) | VAF 94/900 reads (10%) | called by muse, mutect2, varscan2
- ZNF366 | c.1341G>A p.K447= | Silent (SNP) | VAF 31/1004 reads (3%) | catalogued as COSV59216837; called by muse, mutect2
- ALDH3B1 | c.163-73G>T | Intron (SNP) | VAF 9/19 reads (47%) | called by mutect2, varscan2
- DEFB134 | c.-50C>G | 5'UTR (SNP) | VAF 23/172 reads (13%) | catalogued as rs970024113, COSV66363270; called by muse, mutect2, varscan2
- DGCR5 | n.734+802T>A | Intron (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- FBXO4 | c.*35G>T | 3'UTR (SNP) | VAF 96/1056 reads (9%) | catalogued as rs532213620; called by muse, mutect2
- KLRF2 | chr12:9898922 C>T | 3'Flank (SNP) | VAF 135/719 reads (19%) | catalogued as COSV100334709; called by muse, mutect2, varscan2
- KRTAP10-11 | c.*14G>T | 3'UTR (SNP) | VAF 52/356 reads (15%) | called by muse, mutect2, varscan2
- PCNX4 | c.869+38C>A | Intron (SNP) | VAF 136/322 reads (42%) | called by muse, mutect2, varscan2
- PYGO1 | c.-8A>T | 5'UTR (SNP) | VAF 43/236 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.10360+2116G>C | Intron (SNP) | VAF 151/1342 reads (11%) | catalogued as COSV59893797; called by muse, mutect2, varscan2
- ZKSCAN8 | c.*66T>C | 3'UTR (SNP) | VAF 54/230 reads (23%) | called by muse, mutect2, varscan2
